Somatic mutation profile of tumor specimen ALCH-B2FJ-TTP1-A (aliquot ALCH-B2FJ-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2FJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.7 years (27,272 days).
Specimen ALCH-B2FJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5516d64e-b971-471e-8fa2-297514383cce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FJ-NB1-A (Blood Derived Normal), aliquot ALCH-B2FJ-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b217ecf2-f632-4a40-ab05-ac78cc909592

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 2, Intron 2, Frame Shift Del 2, 3'UTR 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY4 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs777977471; called by muse, mutect2, varscan2
- DGKI | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs767223112; called by muse, mutect2, varscan2
- EP300 | c.3829A>C p.K1277Q | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as CM162045; called by muse, mutect2, varscan2
- GABPB1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55014483; called by muse, mutect2, varscan2
- GRID2 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs747630568, COSV56199113; called by muse, mutect2
- HEPH | c.3193C>T p.R1065* (on ENST00000343002; = p.R798* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/177 reads (8%) | catalogued as rs868315515, COSV57967486; called by muse, mutect2
- IQGAP3 | c.4832A>G p.N1611S | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1284542510; called by muse, mutect2
- KIF14 | c.3759T>G p.F1253L | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747056543; called by muse, mutect2, varscan2
- MAPKBP1 | c.904G>A p.V302M (on ENST00000456763 / NM_001128608.2; = p.V296M on NM_014994.3) | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1451298981; called by muse, mutect2, varscan2
- ATP2B1 | c.3475A>G p.I1159V | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CAMTA1 | c.1766T>A p.I589N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCP110 | c.2476_2484+6del p.X826_splice | Splice Site (DEL) | VAF 16/170 reads (9%) | called by mutect2, pindel
- CENPE | c.3048T>A p.D1016E | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.058); called by mutect2, varscan2
- CFAP221 | c.569A>C p.D190A | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- FAM184B | c.1972C>G p.Q658E | Missense Mutation (SNP) | VAF 39/382 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GAD2 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2
- HAS1 | c.361del p.L121Cfs*80 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel, varscan2
- OSBPL7 | c.2018_2022delinsA p.F673* | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by pindel, varscan2*
- TRIM36 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- WNK3 | c.2039C>A p.P680H | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ETFDH | c.1344A>T p.L448= | Silent (SNP) | VAF 30/358 reads (8%) | called by muse, mutect2
- FLOT2 | c.834G>A p.T278= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs754750158, COSV67529490; called by muse, mutect2, varscan2
- INF2 | c.3306G>T p.P1102= | Silent (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- NDUFS1 | c.318A>C p.S106= | Silent (SNP) | VAF 34/486 reads (7%) | called by muse, mutect2
- APBB3 | c.290+25A>T | Intron (SNP) | VAF 55/401 reads (14%) | called by muse, mutect2, varscan2
- FUS | c.-38A>G | 5'UTR (SNP) | VAF 27/269 reads (10%) | catalogued as rs776280427; called by muse, mutect2, varscan2
- IL10RA | c.*1641T>G | 3'UTR (SNP) | VAF 72/690 reads (10%) | called by muse, mutect2, varscan2
- SYNE1 | c.10145+1120_10145+1121del | Intron (DEL) | VAF 22/213 reads (10%) | called by mutect2, pindel, varscan2
